Gene-level copy-number profile of tumor specimen C3N-00307-02 from CPTAC case C3N-00307, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 70.4 years (25,727 days).
Specimen C3N-00307-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f5b34552-422e-4654-b71d-f60f6ca6604a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00307-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/b47ce9bd-bce9-4f11-a5b4-caceb792789a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 58; copy number 1: 16,199; copy number 2: 33,683; copy number 3: 8,617; copy number 4: 100; copy number 5: 221; copy number 6: 17; copy number 7: 1; copy number 9: 9; copy number 11: 8.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,500,512, 7 genes: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799.
- chr9:2,228,961–2,229,241, 1 gene: RN7SL592P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 256 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:167,683,298–183,428,778, 244 genes, copy number 5–9 (broad region; genes not listed).
- chr6:45,328,157–45,664,349, 3 genes, copy number 5 (within-gene range 2–5): RUNX2, AL096865.1, RUNX2-AS1.
- chr11:101,890,674–102,295,806, 9 genes, copy number 7–11: ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1.

Autosomal genes at a single copy (total copy number 1): 13,395. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
